TARGET case TARGET-30-PAKGRH — Neuroblastoma (TARGET-NBL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neuroepitheliomatous Neoplasms; Primary site: Other and ill-defined sites. Index date: not stated by GDC for this case (day counts are relative to an unstated reference).
https://portal.gdc.cancer.gov/cases/15a72a52-c729-50a0-bde3-ecb433a4aefb

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Vital status: Alive.

Diagnoses (1)
1. Neuroblastoma, NOS: ICD-O-3 morphology code: 9500/3; Tissue or organ of origin: Thorax, NOS; Age at diagnosis: 1.9 years (711 days); Year of diagnosis: 2000; Days to last follow up: 1,866 days (5.1 years); INSS stage: Stage 4.

Biospecimens (1 sample)
- Sample TARGET-30-PAKGRH-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.
